Somatic mutation profile of tumor specimen C3L-02504-01 (aliquot CPT0175060006) from CPTAC case C3L-02504, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.9 years (26,277 days).
Specimen C3L-02504-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af6b28ae-24d8-4410-9f2e-cd7297b1e0c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02504-31 (Blood Derived Normal), aliquot CPT0175520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b674702-1886-4c67-b1cc-1e4323a1d479

The open-access MAF lists 80 somatic variants for this specimen: 53 protein-altering or splice-affecting, 18 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Intron 4, Nonsense Mutation 4, Splice Region 3, 5'Flank 3, RNA 1, Frame Shift Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- UNC80 | c.2527C>T p.R843* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as rs74517001; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.4070G>A p.R1357H (on ENST00000506720 / NM_001322402.2; = p.R1246H on NM_015236.6) | Missense Mutation (SNP) | VAF 190/415 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.198); catalogued as rs775577125; called by muse, mutect2, varscan2
- ANGPT4 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs202046919; called by muse, mutect2, varscan2
- ATP10A | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 159/391 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.225); catalogued as rs745958235, COSV100791348; called by muse, mutect2, varscan2
- BOC | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs1436220857; called by muse, mutect2, varscan2
- CPNE5 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 106/283 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55197838; called by muse, mutect2, varscan2
- ENO2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.151); catalogued as rs1555141744, COSV50393381; called by muse, mutect2, varscan2
- FCGBP | c.10427C>T p.P3476L | Missense Mutation (SNP) | VAF 216/556 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1243147058; called by muse, mutect2, varscan2
- FCHSD1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs758942806; called by muse, mutect2
- FRAS1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.586); catalogued as rs761271071; called by muse, mutect2, varscan2
- HLA-DOB | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs1011979502; called by muse, mutect2, varscan2
- IGKV2D-30 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 120/401 reads (30%) | catalogued as rs756764890; called by muse, mutect2, varscan2
- IL12RB1 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 162/423 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.307); catalogued as rs1452899194; called by muse, mutect2, varscan2
- IL1RAPL2 | c.698-1G>T p.X233_splice | Splice Site (SNP) | VAF 42/52 reads (81%) | catalogued as COSV61172447; called by muse, mutect2, varscan2
- IRGQ | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.997); catalogued as rs761500651; called by muse, mutect2, varscan2
- KBTBD13 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1043376338; called by muse, mutect2, varscan2
- LLCFC1 | c.215C>T p.T72M (on ENST00000458732; = p.T41M on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.048); catalogued as rs371951625; called by muse, mutect2, varscan2
- MPO | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 202/449 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs1446697754, COSV99832368; called by muse, mutect2, varscan2
- OR5B2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100222909; called by muse, mutect2, varscan2
- OR5D13 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs755990899, COSV62335690; called by muse, mutect2, varscan2
- OR5P2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs770520472, COSV104412975; called by muse, mutect2, varscan2
- PDGFRA | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 3401/4078 reads (83%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as COSV57265161; called by muse, mutect2, varscan2
- PLK1 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 133/342 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99890740; called by muse, mutect2, varscan2
- PTEN | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104426412; called by muse, mutect2, varscan2
- RASGRP4 | c.511C>T p.L171= | Splice Region (SNP) | VAF 36/97 reads (37%) | catalogued as COSV53095935; called by muse, mutect2, varscan2
- SYNPR | c.19-7C>T | Splice Region (SNP) | VAF 74/165 reads (45%) | catalogued as rs1343633106; called by muse, mutect2, varscan2
- TH | c.838G>A p.G280R (on ENST00000381178 / NM_199292.3; = p.G249R on NM_000360.4) | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749133549; called by muse, mutect2
- WDR59 | c.1507A>G p.S503G | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs759614428; called by muse, mutect2, varscan2
- ZNF432 | c.238+5G>T | Splice Region (SNP) | VAF 60/217 reads (28%) | catalogued as rs768804338; called by muse, mutect2, varscan2
- ADAMTS20 | c.1279T>C p.Y427H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD30B | c.788A>T p.K263I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ATP10A | c.2123G>C p.R708T | Missense Mutation (SNP) | VAF 150/365 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- EIF2AK4 | c.3359T>G p.I1120S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- FAM186A | c.4834G>A p.G1612R | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- GALNT17 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, varscan2
- GALNT17 | c.337G>T p.G113* | Nonsense Mutation (SNP) | VAF 56/196 reads (29%) | called by muse, varscan2
- JMJD7 | c.866del p.N289Ifs*83 | Frame Shift Del (DEL) | VAF 73/190 reads (38%) | called by mutect2, pindel, varscan2
- LRP2 | c.12796G>C p.V4266L | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP2 | c.756T>A p.D252E | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRGPRF | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- MTOR | c.4288G>A p.A1430T | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MYH1 | c.2302T>A p.F768I | Missense Mutation (SNP) | VAF 93/232 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- NR3C2 | c.2336A>G p.Q779R | Missense Mutation (SNP) | VAF 103/275 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PCF11 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 118/326 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PRRC2A | c.3445G>A p.A1149T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PTGS2 | c.1363C>A p.R455S | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- RIF1 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- SDK1 | c.6024G>A p.W2008* | Nonsense Mutation (SNP) | VAF 114/452 reads (25%) | called by muse, mutect2, varscan2
- SF3B1 | c.3320A>C p.Q1107P | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TBR1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VWDE | c.2508G>T p.E836D | Missense Mutation (SNP) | VAF 74/339 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZAP70 | c.820C>G p.P274A | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZAR1L | c.575C>A p.A192D | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANXA13 | c.483T>C p.N161= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as rs764441564; called by muse, mutect2
- APOD | c.216A>G p.G72= | Silent (SNP) | VAF 90/185 reads (49%) | called by muse, mutect2, varscan2
- ATP6V0D2 | c.954A>G p.V318= | Silent (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- DYSF | c.402G>A p.P134= | Silent (SNP) | VAF 16/424 reads (4%) | catalogued as rs973059586, COSV50514950; ClinVar: uncertain significance; called by muse, mutect2
- ECPAS | c.2853C>T p.H951= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs779937190; called by muse, mutect2, varscan2
- EEF1AKNMT | c.480C>T p.S160= (on ENST00000361735 / NM_015935.5; = p.S74= on NM_014955.3) | Silent (SNP) | VAF 111/242 reads (46%) | called by muse, mutect2, varscan2
- HS3ST4 | c.993T>C p.I331= | Silent (SNP) | VAF 157/414 reads (38%) | called by muse, mutect2, varscan2
- IRX3 | c.1191G>A p.L397= | Silent (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- ITGB2 | c.1806C>T p.T602= (on ENST00000302347; = p.T578= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 159/357 reads (45%) | called by muse, mutect2, varscan2
- KCNMB4 | c.231G>A p.R77= | Silent (SNP) | VAF 49/137 reads (36%) | called by muse, mutect2, varscan2
- KRTAP5-10 | c.12T>C p.C4= | Silent (SNP) | VAF 84/223 reads (38%) | called by muse, mutect2
- MPO | c.2232C>T p.A744= | Silent (SNP) | VAF 158/414 reads (38%) | catalogued as COSV51859801; called by muse, mutect2, varscan2
- MYO15A | c.2706G>A p.A902= | Silent (SNP) | VAF 119/274 reads (43%) | catalogued as rs752542493; called by muse, mutect2, varscan2
- RAB35 | c.471G>A p.V157= | Silent (SNP) | VAF 97/220 reads (44%) | called by muse, mutect2, varscan2
- RASAL3 | c.528G>A p.G176= | Silent (SNP) | VAF 89/224 reads (40%) | called by muse, mutect2, varscan2
- RAX | c.412C>A p.R138= | Silent (SNP) | VAF 182/522 reads (35%) | called by muse, mutect2, varscan2
- WNK2 | c.5544C>T p.D1848= (on ENST00000297954 / NM_001282394.1; = p.D1811= on NM_006648.3) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1250751186; called by muse, mutect2, varscan2
- ZAN | c.1374C>T p.G458= | Silent (SNP) | VAF 80/268 reads (30%) | called by muse, mutect2, varscan2
- AC068587.7 | chr8:12659550 G>A | 5'Flank (SNP) | VAF 110/266 reads (41%) | catalogued as rs1278299343; called by muse, varscan2
- AC112198.2 | n.146A>C | RNA (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- ARL13A | c.*378C>A | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- C11orf21 | c.54-142C>A | Intron (SNP) | VAF 109/304 reads (36%) | called by muse, mutect2, varscan2
- DNAH14 | c.6033+2184C>A | Intron (SNP) | VAF 65/197 reads (33%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099644 A>G | 5'Flank (SNP) | VAF 96/452 reads (21%) | called by muse, varscan2
- NRG1 | c.502+31002C>T | Intron (SNP) | VAF 64/164 reads (39%) | called by muse, mutect2, varscan2
- PTPN6 | c.132-46G>A | Intron (SNP) | VAF 125/333 reads (38%) | catalogued as rs1555147847; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159650 C>T | 5'Flank (SNP) | VAF 58/102 reads (57%) | called by muse, mutect2, varscan2
